Somatic mutation profile of tumor specimen TCGA-97-8177-01A (aliquot TCGA-97-8177-01A-11D-2284-08) from TCGA case TCGA-97-8177, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.3 years (21,648 days).
Specimen TCGA-97-8177-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54c096ab-2dd8-4b48-a9b8-2254714ee5ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8177-10A (Blood Derived Normal), aliquot TCGA-97-8177-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f50e5b1c-99bc-4e7e-8f39-5f421c4ea2fd

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Frame Shift Del 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 55/287 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 31/155 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs863225060, COSV55878075, COSV55925758; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCKDHB | c.533del p.G178Efs*52 | Frame Shift Del (DEL) | VAF 17/155 reads (11%) | catalogued as COSV100243543; called by mutect2, varscan2
- BCOR | c.3624A>T p.Q1208H (on ENST00000378444 / NM_001123385.2; = p.Q1174H on NM_017745.6) | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100653634; called by muse, mutect2, varscan2
- BDP1 | c.4801A>C p.I1601L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100703361; called by muse, mutect2
- CCDC91 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.587); catalogued as COSV100082181; called by muse, mutect2, varscan2
- COLEC12 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101232117; called by muse, mutect2, varscan2
- DNAH8 | c.2743C>A p.L915M | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as COSV100546482; called by muse, mutect2, varscan2
- FOXQ1 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.518); catalogued as rs1248996166, COSV99723323; called by muse, mutect2, varscan2
- GRAMD4 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100730576; called by muse, mutect2, varscan2
- HNRNPH2 | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99516503; called by muse, mutect2
- KIF4B | c.544T>A p.L182I | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV101469361; called by muse, mutect2, varscan2
- LAX1 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV65848791; called by muse, mutect2
- MPO | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs773687000, COSV56564812; called by muse, mutect2
- NPTXR | c.850+1G>A p.X284_splice | Splice Site (SNP) | VAF 36/213 reads (17%) | catalogued as COSV100285510, COSV60727803; called by muse, mutect2, varscan2
- PAPPA2 | c.2037C>G p.N679K | Missense Mutation (SNP) | VAF 13/433 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100866916; called by muse, mutect2
- PKHD1 | c.3904G>A p.V1302I | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs141972092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF3B1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV100135261; called by muse, mutect2
- SLC34A2 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769551404, COSV65942034, COSV65942967; called by muse, mutect2, varscan2
- SLC5A7 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV50888881, COSV99887039; called by muse, mutect2, varscan2
- UBR4 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100921370; called by muse, mutect2
- ZNF426 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV99465303; called by muse, mutect2
- IGKV1D-13 | c.159T>A p.S53R | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPL5 | c.415_418del p.P139Vfs*24 | Frame Shift Del (DEL) | VAF 28/269 reads (10%) | called by mutect2, pindel
- ALMS1 | c.1611C>T p.L537= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as COSV100043173; called by muse, mutect2, varscan2
- ANKMY2 | c.279A>G p.K93= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV100187206; called by muse, mutect2, varscan2
- CCDC141 | c.2310C>T p.H770= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs200376493; called by muse, mutect2
- CDX2 | c.477C>A p.G159= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV101122703; called by muse, mutect2, varscan2
- FIG4 | c.1141C>A p.R381= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as CM115116, COSV100020042; called by muse, varscan2
- HOXA10 | c.1232G>A p.*411= | Silent (SNP) | VAF 11/217 reads (5%) | catalogued as COSV99385615; called by muse, mutect2
- OR4F6 | c.789C>T p.P263= | Silent (SNP) | VAF 9/186 reads (5%) | catalogued as COSV100186956; called by muse, mutect2
- PCDHA6 | c.2055C>T p.G685= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as COSV65342972; called by muse, mutect2
- RNF113A | c.255C>T p.S85= | Silent (SNP) | VAF 18/446 reads (4%) | catalogued as COSV65097762; called by muse, mutect2
- SLC5A10 | c.1017G>A p.L339= (on ENST00000395645 / NM_001042450.4; = p.L355= on NM_152351.5) | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV100525357; called by muse, mutect2
- ST18 | c.1875C>T p.D625= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV99390454; called by muse, mutect2, varscan2
- VPS26C | chr21:37221366 T>C | 3'Flank (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
